Gene-level copy-number profile of tumor specimen REBC-ACCY-TTP1-A from REBC case REBC-ACCY, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACCY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61ebb400-7761-444d-b1e8-4f07697d61bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACCY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/868377b4-e129-4174-90ea-33800c090765

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,909; copy number 2: 55,869; copy number 3: 25; copy number 4: 93.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:133,623,895–133,778,699, 20 genes: FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
